Somatic mutation profile of tumor specimen 0E1SY2 from CCDI case PBCWMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1SY2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca40d248-67b7-4380-a3ef-fb742025bb15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1SXY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09964ab0-9a20-44af-8157-04fbd09d31ca

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT3 | c.3641G>A p.R1214Q | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs998069748; called by muse, mutect2, varscan2
- FGF11 | c.496C>A p.R166S | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV53441363; called by muse, mutect2
- NYAP2 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 114/210 reads (54%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.994); catalogued as COSV56015572; called by muse, mutect2, varscan2
- RIMS2 | c.4585C>T p.R1529C (on ENST00000666250 / NM_001348490.2; = p.R1100C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 224/529 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775205197; called by muse, mutect2, varscan2
- SPINK5 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 194/459 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); catalogued as rs576310290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK13 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- GBF1 | c.2164C>T p.L722= (on ENST00000369983 / NM_001377137.1; = p.L721= on NM_004193.3) | Silent (SNP) | VAF 150/343 reads (44%) | called by muse, mutect2, varscan2
- KAT6A | c.4182C>T p.D1394= | Silent (SNP) | VAF 172/366 reads (47%) | catalogued as rs150230451; called by muse, mutect2, varscan2
- RPN1 | c.1695G>T p.S565= | Silent (SNP) | VAF 30/376 reads (8%) | catalogued as COSV56189485; called by muse, mutect2
- LINC02873 | n.101C>T | RNA (SNP) | VAF 76/218 reads (35%) | catalogued as rs369196412; called by muse, mutect2, varscan2
